Gene-level copy-number profile of tumor specimen TCGA-3P-A9WA-01A from TCGA case TCGA-3P-A9WA, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 55.3 years (20,211 days).
Specimen TCGA-3P-A9WA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.997c7fe1-5f90-4aeb-983d-6d36bac3b03b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3P-A9WA-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ef861ff-bca6-4702-8ea6-459269c97786

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 958; copy number 2: 15,616; copy number 3: 4,358; copy number 4: 32,976; copy number 5: 2,389; copy number 6: 2,277; copy number 7: 1,031; copy number 8: 87; copy number 9: 110; copy number 10: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3P-A9WA-01A-11D-A402-01): tumor purity 0.85, ploidy 3.5, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 119 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:148,850,933–148,960,112, 3 genes, copy number 10 (within-gene range 7–10): AC092979.1, CPA3, AC092979.2.
- chr3:172,425,850–172,604,006, 6 genes, copy number 9: BZW1P1, GHSR, TNFSF10, AC007919.1, LINC02068, SLC31A1P1.
- chr7:83,017,898–83,664,625, 6 genes, copy number 10: RNA5SP235, AC079799.1, SEMA3E, AC079799.2, AC079987.1, RAD23BP2.
- chr11:112,175,510–112,224,699, 1 gene, copy number 9 (within-gene range 6–9): BCO2.
- chr11:112,208,601–112,835,124, 17 genes, copy number 9: MRPS36P4, RPS12P21, PTS, RPS6P16, PLET1, AP002884.3, ST13P10, LINC02762, RNU6-44P, LINC02763, RPL23AP62, LINC02764, AP003063.1, AP003100.2, AP003100.3, AP003100.1, AC016902.1.
- chr16:79,202,624–79,606,605, 8 genes, copy number 9: AC092376.2, AC092376.3, AC092376.1, RNA5SP431, AC084064.1, MAF, AC009159.2, AC009159.3.
- chr17:39,546,104–40,304,657, 38 genes, copy number 9: RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA, PSMD3, AC090844.3, CSF3, MED24, MIR6884, SNORD124, THRA, NR1D1, AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867, WIPF2, CDC6.
- chr17:40,317,698–40,318,676, 1 gene, copy number 9: AC080112.4.
- chr20:34,955,810–35,454,746, 21 genes, copy number 9 (within-gene range 6–9): MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5.
- chr20:49,038,357–49,713,878, 18 genes, copy number 9 (within-gene range 6–9): SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS, B4GALT5.

Autosomal genes at a single copy (total copy number 1): 958. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
